Somatic mutation profile of tumor specimen TCGA-2F-A9KT-01A (aliquot TCGA-2F-A9KT-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KT, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-2F-A9KT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86c836e-1eb7-456c-8a86-297a252e8734.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KT-10A (Blood Derived Normal), aliquot TCGA-2F-A9KT-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3329f1d-667b-4547-a392-d1bdbc953a26

The open-access MAF lists 390 somatic variants for this specimen: 309 protein-altering or splice-affecting, 75 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 75, Nonsense Mutation 31, Splice Site 5, Splice Region 3, Intron 3, In Frame Del 2, Frame Shift Del 2, 5'Flank 2, Nonstop Mutation 2, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLT4 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451816005, CM032232, CM1311596, COSV56098538; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2092C>T p.Q698* | Nonsense Mutation (SNP) | VAF 45/158 reads (28%) | catalogued as rs63750832, CM990715, COSV52279974, COSV99316104; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMARCA2 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs281875186, CM122553, COSV61805232, COSV61807107; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB6 | c.1696G>C p.D566H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54697586; called by muse, mutect2, varscan2
- AC093525.2 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | PolyPhen benign (0); catalogued as rs766645348, COSV53552073, COSV99565580; called by muse, mutect2, varscan2
- ACAD9 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.046); catalogued as COSV58309548; called by muse, mutect2, varscan2
- ACSM2B | c.1712C>T p.S571F | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs767639030, COSV61656916; called by muse, mutect2, varscan2
- ADAMTS13 | c.3693G>C p.E1231D | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV52471316; called by muse, mutect2, varscan2
- ADGRL4 | c.1531G>T p.E511* | Nonsense Mutation (SNP) | VAF 21/113 reads (19%) | catalogued as COSV100876062, COSV66061723; called by muse, mutect2, varscan2
- AFDN | c.4529G>A p.S1510N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs974671882, COSV60053663; called by muse, mutect2, varscan2
- AFP | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as COSV56926674; called by muse, mutect2, varscan2
- AFTPH | c.2506G>A p.D836N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1475502808, COSV99480829; called by muse, mutect2, varscan2
- AGR3 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV60039357; called by muse, mutect2, varscan2
- AGTPBP1 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV100430280, COSV61276121; called by muse, mutect2, varscan2
- AHI1 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.1); catalogued as COSV55634299; called by muse, mutect2, varscan2
- AHNAK | c.14379C>G p.F4793L | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.901); catalogued as COSV57206510, COSV57226377; called by muse, mutect2, varscan2
- AKAP1 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as COSV58472345; called by muse, mutect2, varscan2
- AKAP9 | c.10828G>A p.E3610K (on ENST00000359028; = p.E3586K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV62355444; called by muse, mutect2, varscan2
- AL592490.1 | c.2855G>C p.*952Sext*6 | Nonstop Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV101308216; called by muse, mutect2, varscan2
- ALDH1L2 | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | catalogued as COSV99311088; called by muse, mutect2, varscan2
- AMMECR1L | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as COSV55761668, COSV99761180; called by muse, mutect2, varscan2
- AMZ2 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); catalogued as COSV63083624; called by muse, mutect2, varscan2
- ANK1 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55892464; called by muse, mutect2, varscan2
- ANO1 | c.558G>C p.E186D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.066); catalogued as rs370335049; called by muse, mutect2, varscan2
- APBB1IP | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV63303247, COSV63303971; called by muse, mutect2, varscan2
- ARHGAP45 | c.663C>A p.F221L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1167469513, COSV100490766; called by muse, mutect2, varscan2
- ASH1L | c.7497G>T p.Q2499H (on ENST00000368346 / NM_001366177.2; = p.Q2494H on NM_018489.3) | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV64207044; called by muse, mutect2, varscan2
- ATAD2 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV54885431; called by muse, mutect2, varscan2
- ATF7 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338586322, COSV60645842; called by muse, mutect2, varscan2
- ATF7IP | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV53776122; called by muse, mutect2, varscan2
- ATP12A | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99517763; called by muse, mutect2, varscan2
- ATP13A3 | c.3024C>G p.F1008L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55468676; called by muse, mutect2, varscan2
- ATP2B4 | c.2038G>C p.D680H | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV58182587; called by muse, mutect2, varscan2
- ATP8B4 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | catalogued as COSV52713194, COSV99463125; called by muse, mutect2, varscan2
- AZIN2 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756639325, COSV53857365; called by muse, mutect2, varscan2
- B3GALT2 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66464472; called by muse, mutect2, varscan2
- BAG3 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142391650, COSV64842566; called by muse, mutect2, varscan2
- BAHD1 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 28/95 reads (29%) | catalogued as COSV69084254; called by muse, mutect2, varscan2
- BAHD1 | c.1271C>G p.S424* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV101346765; called by muse, mutect2, varscan2
- BAZ2A | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as COSV51642287; called by muse, mutect2, varscan2
- BLVRB | c.518C>G p.S173* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99647932; called by muse, mutect2, varscan2
- CACNA1A | c.4385G>A p.G1462E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1257081807, COSV64209656; called by muse, mutect2, varscan2
- CAMSAP1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56721558, COSV56727091; called by muse, mutect2, varscan2
- CCDC150 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV55877729; called by muse, mutect2, varscan2
- CCDC190 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV63363479; called by muse, mutect2, varscan2
- CCHCR1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs745730901, COSV66184928; called by muse, mutect2
- CD79A | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as COSV55739385; called by muse, mutect2, varscan2
- CDH22 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 27/335 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.035); catalogued as COSV64836482, COSV64839245; called by muse, mutect2
- CDH4 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.879); catalogued as rs773008947, COSV64670591; called by muse, mutect2, varscan2
- CDH4 | c.2657C>T p.S886F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs373099894; called by muse, mutect2, varscan2
- CDHR5 | c.1847C>A p.S616Y (on ENST00000358353 / NM_001171968.2; = p.S622Y on NM_021924.5) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as rs71469809, COSV57645557; called by muse, varscan2
- CDHR5 | c.1813C>T p.Q605* (on ENST00000358353 / NM_001171968.2; = p.Q611* on NM_021924.5) | Nonsense Mutation (SNP) | VAF 32/100 reads (32%) | catalogued as COSV100363537; called by muse, varscan2
- CDHR5 | c.1319C>T p.S440F | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as COSV57645560; called by muse, varscan2
- CDHR5 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs548971527, COSV57645564; called by muse, mutect2, varscan2
- CEP104 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as rs750473230, COSV65519184; called by muse, mutect2, varscan2
- CEP104 | c.891G>A p.L297= | Splice Region (SNP) | VAF 35/127 reads (28%) | catalogued as rs375030493; called by muse, mutect2, varscan2
- CHD2 | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs1218211742, COSV67713521; called by muse, varscan2
- CHD6 | c.4434G>A p.W1478* | Nonsense Mutation (SNP) | VAF 76/242 reads (31%) | catalogued as COSV100951081; called by muse, varscan2
- CHD7 | c.4070C>G p.S1357C | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71108789, COSV71113692; called by muse, mutect2, varscan2
- CHRD | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as COSV52611594; called by muse, mutect2, varscan2
- CHRNB1 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.557); catalogued as COSV60141964; called by muse, mutect2
- CIDEA | c.528C>G p.F176L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57600168; called by muse, mutect2, varscan2
- CIITA | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1422461877, COSV60861074; called by muse, varscan2
- CKAP5 | c.1533G>T p.K511N | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.15); catalogued as COSV56372945; called by muse, mutect2, varscan2
- CLCN2 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55603577; called by muse, mutect2, varscan2
- CNPY3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.621); catalogued as COSV65710013; called by muse, varscan2
- CNR2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV65694125; called by muse, mutect2, varscan2
- COL4A4 | c.3787C>T p.Q1263* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV61632295; called by muse, mutect2, varscan2
- CPB2 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99473115; called by muse, mutect2, varscan2
- CPSF4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV52858971; called by muse, mutect2, varscan2
- CSNK1E | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as rs1388037223, COSV100725041; called by muse, mutect2, varscan2
- CYRIA | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV62866720; called by muse, mutect2, varscan2
- CZIB | c.230-1G>C p.X77_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | catalogued as COSV53760137; called by muse, mutect2, varscan2
- DBNDD1 | c.226G>A p.D76N (on ENST00000002501 / NM_001042610.3; = p.D96N on NM_024043.3) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216206310, COSV99136481; called by muse, mutect2, varscan2
- DDI1 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100159330, COSV56390718; called by muse, mutect2, varscan2
- DDX17 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53254022; called by muse, mutect2, varscan2
- DLGAP3 | c.1842G>C p.K614N | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.236); catalogued as COSV99332790; called by muse, mutect2
- DNAH7 | c.8197G>T p.E2733* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as rs1313430203, COSV100415501; called by muse, mutect2, varscan2
- DPP4 | c.1567+1G>T p.X523_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as rs1490229251, COSV62109101; called by muse, varscan2
- DPY30 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV54459775; called by muse, mutect2, varscan2
- DST | c.12247C>A p.Q4083K (on ENST00000361203 / NM_001374722.1; = p.Q1671K on NM_015548.5) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV99756814; called by muse, mutect2
- EFCAB6 | c.2638G>C p.D880H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV53070484; called by muse, mutect2, varscan2
- EIF2AK4 | c.2200G>A p.E734K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1491003149, COSV55472982; called by muse, mutect2, varscan2
- ELAVL1 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100688381; called by muse, mutect2, varscan2
- ELF3 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100668799; called by muse, mutect2
- ELMOD2 | c.500G>C p.R167T | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60271317; called by muse, mutect2, varscan2
- EME1 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56812879, COSV56813131; called by muse, varscan2
- EME1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV56812822; called by muse, varscan2
- EME1 | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV56813138; called by muse, mutect2, varscan2
- EPC2 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51540703, COSV51548315; called by muse, mutect2, varscan2
- EPHA10 | c.1921G>C p.D641H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV57626591; called by muse, mutect2
- EPS8L2 | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV100585343, COSV59349882; called by muse, mutect2, varscan2
- ERBB2 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54072516, COSV99508121; called by muse, mutect2, varscan2
- ETNPPL | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV56597184; called by muse, mutect2, varscan2
- EXOC4 | c.2860G>C p.E954Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV54116654; called by muse, mutect2, varscan2
- FAM102A | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV66194678; called by muse, mutect2, varscan2
- FAM151A | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.435); catalogued as COSV100156940, COSV56364090; called by muse, mutect2
- FAM216A | c.641C>G p.S214C | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV62195389; called by muse, mutect2, varscan2
- FAM83G | c.2008C>T p.Q670* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs748573813, COSV100525184; called by muse, mutect2, varscan2
- FANCD2 | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as COSV55044780; called by muse, mutect2, varscan2
- FANK1 | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV64135527; called by muse, mutect2, varscan2
- FASN | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV60759870; called by muse, mutect2, varscan2
- FIGLA | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV60089778; called by muse, mutect2, varscan2
- FLRT2 | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV58148451; called by muse, mutect2, varscan2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- FRS2 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV54728651; called by muse, mutect2, varscan2
- FSD2 | c.2185G>C p.E729Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100575161; called by muse, mutect2, varscan2
- GLIS1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1316762566, COSV56547369; called by muse, mutect2, varscan2
- GPR4 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV59917993; called by muse, mutect2, varscan2
- GRID1 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV60047866; called by muse, mutect2, varscan2
- GRIN2D | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.266); catalogued as rs1263136397, COSV54381653; called by muse, mutect2, varscan2
- GSTCD | c.1446G>C p.K482N (on ENST00000360505 / NM_001031720.3; = p.K395N on NM_024751.3) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV64735204; called by muse, mutect2, varscan2
- HAUS8 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV53727173, COSV99505541; called by muse, mutect2
- HCFC2 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57560055; called by muse, mutect2, varscan2
- HGF | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.67); catalogued as rs372600489; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HLA-DRA | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs772228928, COSV66623054; called by muse, mutect2, varscan2
- HMX2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV60593304; called by muse, mutect2, varscan2
- HS3ST3A1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.362); catalogued as rs1228822657, COSV52380133; called by muse, mutect2
- IGHV4-34 | c.186G>C p.W62C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs11546807; called by muse, mutect2, varscan2
- IGSF1 | c.1751-1G>A p.X584_splice | Splice Site (SNP) | VAF 21/37 reads (57%) | catalogued as COSV63839533; called by muse, mutect2, varscan2
- IGSF9 | c.928C>G p.P310A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100829633; called by muse, mutect2
- IGSF9B | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as rs1229502334, COSV58071647; called by muse, mutect2, varscan2
- IQCN | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV66576939; called by muse, mutect2, varscan2
- IRF3 | c.1010G>C p.G337A | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs1416297269, COSV99881652; called by muse, mutect2, varscan2
- KCNA6 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV54977093; called by muse, mutect2, varscan2
- KCNJ12 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1555562535, COSV59164401; called by muse, mutect2, varscan2
- KCNQ5 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59677893; called by muse, mutect2, varscan2
- KHDC4 | c.1529C>G p.S510* | Nonsense Mutation (SNP) | VAF 45/145 reads (31%) | catalogued as COSV100850817; called by muse, mutect2, varscan2
- KIF13B | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV73054652; called by muse, mutect2, varscan2
- KIF9 | c.2314G>C p.E772Q (on ENST00000265529 / NM_001377474.1; = p.E707Q on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.262); catalogued as COSV55522886; called by muse, mutect2, varscan2
- KLHL2 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.153); catalogued as rs373958025; called by muse, mutect2, varscan2
- KMT2C | c.5371C>T p.Q1791* | Nonsense Mutation (SNP) | VAF 37/152 reads (24%) | catalogued as COSV51427498; called by muse, mutect2, varscan2
- KMT2C | c.3612del p.K1205Nfs*2 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as COSV51488418; called by mutect2, pindel, varscan2
- KRT71 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs552558218, COSV57290905; called by muse, mutect2, varscan2
- LIPH | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs532157600, COSV56183118, COSV56185525; called by muse, mutect2, varscan2
- LRPPRC | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs754855090, COSV53237156, COSV99580788; called by muse, mutect2, varscan2
- LRRC17 | c.-143C>T | Splice Region (SNP) | VAF 13/60 reads (22%) | catalogued as COSV50867373; called by muse, mutect2, varscan2
- LRRK2 | c.3954C>G p.I1318M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54166778; called by muse, mutect2
- LTBP4 | c.851C>T p.S284L (on ENST00000308370 / NM_001042544.1; = p.S247L on NM_003573.2) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs761342071, COSV99193376; called by muse, mutect2
- LYRM1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1247530649, COSV54644479; called by muse, mutect2
- MACF1 | c.15043C>A p.Q5015K (on ENST00000372915; = p.Q2948K on NM_012090.5) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV57138923; called by muse, mutect2, varscan2
- MAGEB6B | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as rs879157758, COSV69689890; called by muse, mutect2, varscan2
- MAGI1 | c.3178C>A p.R1060S (on ENST00000402939 / NM_001033057.2; = p.R1089S on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV58340438; called by muse, mutect2, varscan2
- MAP7 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1215808852, COSV63422371, COSV63422854; called by muse, mutect2
- MAPK8IP3 | c.2776G>A p.D926N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV51725618; called by muse, mutect2, varscan2
- MAST1 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV52253101; called by muse, mutect2, varscan2
- MAT2A | c.1059C>G p.F353L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52090000; called by muse, mutect2, varscan2
- MAZ | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as COSV99361199; called by muse, mutect2, varscan2
- MED12L | c.5917C>G p.P1973A | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.038); catalogued as COSV56393261, COSV99854407; called by muse, mutect2, varscan2
- MMAA | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as rs757207009, COSV55579937; called by muse, mutect2, varscan2
- MON2 | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV54813318; called by muse, mutect2, varscan2
- MON2 | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54813337; called by muse, mutect2, varscan2
- MORC1 | c.1201G>C p.V401L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV51728537; called by muse, mutect2, varscan2
- MUC16 | c.11336C>A p.S3779Y | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.743); catalogued as COSV101200307, COSV67486924, COSV67486990; called by muse, mutect2, varscan2
- MYNN | c.1297C>T p.H433Y | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62992094; called by muse, mutect2, varscan2
- MYO1E | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.206); catalogued as rs778389437, COSV55693604; called by muse, mutect2, varscan2
- MYO7B | c.5589G>C p.L1863F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100264733; called by muse, mutect2, varscan2
- NALCN | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV51958698; called by muse, mutect2, varscan2
- NECAP1 | c.827G>C p.*276Sext*7 | Nonstop Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100331595; called by muse, mutect2, varscan2
- NFKBIA | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV53752751, COSV99395174; called by muse, mutect2
- NIBAN1 | c.1963G>A p.V655M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs376519532, COSV62287204; called by muse, mutect2, varscan2
- NOD1 | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV56114334; called by muse, mutect2, varscan2
- NOD1 | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as COSV56114345; called by muse, mutect2, varscan2
- NOTCH1 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs779794980, COSV53043673, COSV53078888; called by muse, mutect2, varscan2
- NOTCH1 | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); catalogued as COSV53082664; called by muse, mutect2, varscan2
- NOTCH3 | c.4759G>A p.D1587N | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657487; called by muse, mutect2, varscan2
- NOX1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54196238; called by muse, mutect2, varscan2
- NSD2 | c.3032C>T p.S1011L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56387456; called by muse, mutect2, varscan2
- NSD2 | c.3318C>G p.I1106M | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100372923, COSV56395253; called by muse, mutect2, varscan2
- NSMAF | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50697649; called by muse, mutect2, varscan2
- OBSCN | c.2837G>A p.R946K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV52803794, COSV52815667; called by muse, mutect2, varscan2
- OCEL1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52245081; called by muse, mutect2, varscan2
- OR2L3 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1435508843, COSV63454358; called by muse, mutect2, varscan2
- OR7E24 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV71702327; called by muse, mutect2, varscan2
- OTX2 | c.471C>G p.I157M (on ENST00000408990 / NM_172337.3; = p.I165M on NM_021728.4) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV59767035; called by muse, mutect2, varscan2
- P4HTM | c.1074-2A>C p.X358_splice (on ENST00000383729 / NM_177939.3; = p.S419R on NM_177938.2) | Splice Site (SNP) | VAF 11/66 reads (17%) | catalogued as COSV59088730; called by muse, mutect2, varscan2
- PAK1IP1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV65435891; called by muse, mutect2, varscan2
- PARP8 | c.1881G>T p.K627N | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55865488; called by muse, mutect2, varscan2
- PGBD4 | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56628873; called by muse, mutect2, varscan2
- PIK3C3 | c.1298C>A p.S433Y | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as rs1260003181, COSV56276366, COSV56284061; called by muse, mutect2, varscan2
- PJA1 | c.1027C>T p.R343C (on ENST00000361478 / NM_145119.4; = p.R155C on NM_022368.5) | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1333575502, COSV64053651; called by muse, mutect2, varscan2
- PKP4 | c.632G>A p.R211K | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.194); catalogued as COSV67676984; called by muse, mutect2, varscan2
- PLXNB1 | c.1706C>T p.S569F | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV56493341; called by muse, varscan2
- PNPLA5 | c.1056C>G p.F352L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53376060, COSV99336670; called by muse, mutect2, varscan2
- POT1 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554423983, COSV62929238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPM1E | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV57578691; called by muse, mutect2, varscan2
- PPP1R3A | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV52890976; called by muse, mutect2, varscan2
- PRH1 | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs369033829; called by muse, mutect2, varscan2
- PRKAR1B | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383315406, COSV64319714; called by muse, mutect2, varscan2
- PRKCQ | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54109413; called by muse, mutect2, varscan2
- PRKCSH | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52953446; called by muse, mutect2, varscan2
- PRPF19 | c.1271T>G p.L424R | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57129025; called by muse, mutect2, varscan2
- PRPF4B | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.616); catalogued as COSV61785405; called by muse, mutect2, varscan2
- PRPF6 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); catalogued as COSV53876694; called by muse, mutect2, varscan2
- PRX | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.919); catalogued as rs772009400, COSV52529269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSD2 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV51207959; called by mutect2, varscan2
- PSIP1 | c.1424C>G p.S475* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV101050938; called by muse, mutect2, varscan2
- PSMA8 | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100378919; called by muse, mutect2, varscan2
- PSORS1C1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV52536375, COSV52536660; called by muse, mutect2, varscan2
- PXYLP1 | c.676G>C p.D226H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53892562; called by muse, mutect2, varscan2
- RASGRP2 | c.1342C>G p.Q448E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV62450625; called by muse, varscan2
- RBFA | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV51534922; called by muse, mutect2
- RBM10 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1556778215, COSV100237969, COSV61309818; called by muse, mutect2, varscan2
- RBM34 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV64013276; called by muse, mutect2, varscan2
- RBMXL2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100182279; called by muse, mutect2
- RBSN | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV53794039; called by muse, mutect2, varscan2
- RIF1 | c.712C>T p.Q238* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99690645; called by muse, mutect2, varscan2
- RIPK3 | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53476950; called by muse, mutect2, varscan2
- RNF217 | c.1174G>A p.E392K (on ENST00000521654 / NM_001286398.2; = p.E100K on NM_152553.5) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.686); catalogued as COSV51577227, COSV99255340; called by muse, mutect2, varscan2
- ROBO1 | c.1262C>G p.S421C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV71397701; called by muse, mutect2, varscan2
- RTN4IP1 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1327054264, COSV64688034; called by muse, mutect2, varscan2
- RYR2 | c.12460G>A p.E4154K | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV63707385; called by muse, mutect2, varscan2
- SACS | c.4264G>A p.V1422M | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1234960500, COSV66545681; called by muse, mutect2, varscan2
- SART3 | c.1616A>G p.H539R (on ENST00000228284; = p.H521R on NM_014706.4) | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs144381891; called by muse, mutect2, varscan2
- SBF1 | c.5599C>T p.R1867C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754888523, COSV53297367; called by muse, mutect2, varscan2
- SEC16B | c.2158C>T p.H720Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1192968776, COSV100381633; called by muse, mutect2, varscan2
- SEC61A2 | c.947T>A p.F316Y | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as COSV53654432; called by muse, mutect2, varscan2
- SERINC5 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV101549096; called by muse, mutect2, varscan2
- SESTD1 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV58932531; called by muse, mutect2, varscan2
- SETX | c.2869C>G p.Q957E | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV56392553; called by muse, mutect2, varscan2
- SGPP1 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV55976369, COSV55976818; called by muse, mutect2, varscan2
- SH3TC1 | c.843G>A p.W281* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99794923; called by muse, mutect2, varscan2
- SIGLEC1 | c.3523C>G p.L1175V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.942); catalogued as COSV52470491; called by mutect2, varscan2
- SIK2 | c.1552G>T p.D518Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV59255387; called by muse, mutect2
- SIN3A | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as COSV64583257; called by muse, mutect2, varscan2
- SIN3A | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1173797523, COSV64582255; called by muse, mutect2, varscan2
- SLC18A2 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.617); catalogued as COSV53692933; called by muse, mutect2, varscan2
- SLC18A3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs754259907, COSV60331226; called by muse, varscan2
- SLC25A16 | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs1321676763, COSV56265984; called by muse, mutect2, varscan2
- SLC26A4 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as COSV99707108; called by muse, mutect2, varscan2
- SLC27A1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs371654438; called by muse, mutect2, varscan2
- SLIT1 | c.1651G>C p.E551Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as COSV56596961; called by muse, mutect2, varscan2
- SMC1A | c.2475G>C p.K825N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV59131402; called by muse, mutect2, varscan2
- SORCS1 | c.1053G>C p.Q351H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.26); catalogued as COSV53896843, COSV99550911; called by muse, mutect2, varscan2
- SOX7 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58730459, COSV58731496; called by muse, mutect2, varscan2
- SP2 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV65064952; called by muse, mutect2, varscan2
- SPAG5 | c.840G>C p.M280I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as COSV58803872; called by muse, mutect2, varscan2
- SPATA4 | c.367T>A p.F123I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as COSV54591437; called by muse, mutect2, varscan2
- SSH3 | c.1972G>T p.E658* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100354599, COSV57383865; called by muse, mutect2, varscan2
- ST3GAL3 | c.292G>A p.E98K (on ENST00000361392 / NM_174964.4; = p.E83K on NM_006279.5) | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV53519238; called by muse, varscan2
- ST3GAL4 | c.438-1G>C p.X146_splice (on ENST00000392669 / NM_001254758.1; = p.X142_splice on NM_006278.3) | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV57109384; called by muse, mutect2, varscan2
- STAU1 | c.1247G>C p.G416A (on ENST00000371856 / NM_001319135.1; = p.G335A on NM_004602.3) | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61462079; called by muse, mutect2, varscan2
- STK19 | c.727C>A p.L243I (on ENST00000375333 / NM_032454.1; = p.L239I on NM_004197.1) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); catalogued as COSV64692756; called by muse, mutect2, varscan2
- SYCP2 | c.3973C>G p.H1325D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV62770931, COSV62771639; called by muse, mutect2, varscan2
- SYNE1 | c.6877G>C p.E2293Q (on ENST00000367255 / NM_182961.4; = p.E2300Q on NM_033071.3) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV55073686; called by muse, mutect2, varscan2
- TAF9 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54204509; called by muse, varscan2
- TAF9 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.214); catalogued as COSV54205258; called by muse, varscan2
- TARBP1 | c.4192C>G p.Q1398E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1381465377, COSV50200144; called by muse, mutect2, varscan2
- TAS2R20 | c.920C>G p.S307* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs1402317265, COSV101114955, COSV67861197; called by muse, varscan2
- TAS2R20 | c.586C>G p.L196V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.764); catalogued as COSV67853383, COSV67861648; called by muse, mutect2, varscan2
- TBC1D32 | c.3215C>T p.S1072F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51547416; called by muse, mutect2, varscan2
- TBC1D9 | c.3294G>C p.K1098N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV71308548; called by muse, mutect2, varscan2
- TBL3 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60342750; called by muse, mutect2
- TENM3 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV69304027, COSV69317427; called by muse, mutect2, varscan2
- TFB1M | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1349104288, COSV65698409; called by muse, mutect2, varscan2
- TIAM2 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as COSV59701432; called by muse, mutect2, varscan2
- TMEM132E | c.2500G>A p.E834K (on ENST00000321639; = p.E924K on NM_001304438.2) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1233870562, COSV58694672; called by muse, mutect2, varscan2
- TMEM209 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV61023428; called by muse, mutect2, varscan2
- TMEM87A | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1241727865, COSV67747898; called by muse, mutect2, varscan2
- TOMM34 | c.887C>A p.P296H | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV53842371; called by muse, mutect2, varscan2
- TRAPPC10 | c.1422G>T p.R474S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52380654; called by muse, mutect2, varscan2
- TRIM75P | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs758316683, COSV72295894; called by muse, mutect2, varscan2
- TRPV5 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as rs773132527, COSV54688943; called by muse, mutect2, varscan2
- TTC29 | c.119A>G p.D40G | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV100283903; called by muse, mutect2
- TTLL6 | c.2626G>A p.A876T (on ENST00000393382 / NM_001130918.3; = p.A569T on NM_173623.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.03); catalogued as COSV64977054; called by muse, mutect2, varscan2
- TUBB2A | c.1134C>G p.F378L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100373902; called by muse, mutect2, varscan2
- TYK2 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs1308330667, COSV53390929; called by muse, mutect2, varscan2
- UPF2 | c.2911G>C p.D971H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.935); catalogued as COSV62661106, COSV62663010; called by muse, mutect2, varscan2
- UPK3A | c.573C>G p.L191= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV53415240; called by muse, mutect2, varscan2
- URB2 | c.3087C>G p.F1029L | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV51024518; called by muse, mutect2, varscan2
- USP25 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as rs1434430164, COSV99583897; called by muse, mutect2, varscan2
- USP42 | c.3677C>G p.S1226C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1390463848, COSV60363601; called by muse, mutect2, varscan2
- UTRN | c.9750G>C p.Q3250H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV62312100; called by muse, mutect2, varscan2
- VAV1 | c.941G>C p.R314T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58390181; called by muse, mutect2, varscan2
- WDR33 | c.1483C>G p.P495A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59254570; called by muse, varscan2
- WNK2 | c.5128G>A p.V1710I (on ENST00000297954 / NM_001282394.1; = p.V1673I on NM_006648.3) | Missense Mutation (SNP) | VAF 53/106 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs140544829; called by muse, mutect2, varscan2
- XBP1 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV53276229; called by muse, mutect2, varscan2
- YEATS2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59371303; called by muse, mutect2, varscan2
- ZC2HC1A | c.78C>G p.F26L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55670991, COSV55671658; called by muse, mutect2, varscan2
- ZC3H4 | c.2338G>C p.E780Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53416268; called by muse, mutect2, varscan2
- ZC3H4 | c.2179G>A p.E727K | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.115); catalogued as rs1241063092, COSV53415000; called by muse, mutect2, varscan2
- ZCCHC8 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as COSV60317182; called by muse, mutect2, varscan2
- ZHX2 | c.1762G>T p.E588* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100073215, COSV58716262; called by muse, mutect2, varscan2
- ZNF207 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as COSV58301618; called by muse, mutect2, varscan2
- ZNF273 | c.715_717del p.C239del | In Frame Del (DEL) | VAF 16/85 reads (19%) | catalogued as COSV60400287; called by mutect2, pindel, varscan2
- ZNF277 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1163435733, COSV62465882; called by muse, mutect2, varscan2
- ZNF33A | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV56727253; called by muse, mutect2, varscan2
- ZNF35 | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV56077294; called by muse, mutect2, varscan2
- ZNF358 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.927); catalogued as rs1366712735, COSV51179349; called by muse, mutect2, varscan2
- ZNF429 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV61918409; called by muse, mutect2, varscan2
- ZNF430 | c.615C>G p.F205L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.803); catalogued as COSV55112076; called by muse, mutect2, varscan2
- ZNF493 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1397423682, COSV62751624; called by muse, mutect2, varscan2
- ZNF493 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1033858784, COSV62749455, COSV62751631; called by muse, mutect2, varscan2
- ZNF493 | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100828778, COSV62749765, COSV62751236; called by muse, mutect2, varscan2
- ZNF557 | c.744G>C p.L248F (on ENST00000414706 / NM_001044388.2; = p.L255F on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV53275086; called by muse, mutect2, varscan2
- ZNF565 | c.411C>G p.F137L (on ENST00000355114; = p.F97L on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/190 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV58411555; called by muse, mutect2, varscan2
- ZNF585A | c.2269C>T p.Q757* (on ENST00000292841 / NM_001288800.2; = p.Q702* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 32/124 reads (26%) | catalogued as COSV99493210; called by muse, mutect2, varscan2
- ZNF596 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs985068189, COSV57655134; called by muse, mutect2, varscan2
- ZNF710 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51565142; called by muse, mutect2, varscan2
- ZNF761 | c.588C>G p.F196L | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.397); catalogued as COSV61889310; called by muse, mutect2, varscan2
- ZNF780A | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.95); catalogued as COSV61816344; called by muse, mutect2, varscan2
- ZPR1 | c.635A>T p.Q212L | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57064717; called by muse, mutect2, varscan2
- ZSCAN10 | c.956G>A p.R319H (on ENST00000252463; = p.R374H on NM_032805.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs769261525, COSV52970225; called by muse, mutect2, varscan2
- EPHA4 | c.171_174del p.I59Wfs*16 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- LHX1 | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBM5 | c.2298_2299dup p.Q767Lfs*14 | Frame Shift Ins (INS) | VAF 29/118 reads (25%) | called by mutect2, pindel, varscan2
- TOMM40L | c.159_161del p.N53del | In Frame Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- TRAJ57 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- AGAP2 | c.939C>A p.P313= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1484565031, COSV57730926; called by muse, mutect2, varscan2
- AGT | c.1213C>T p.L405= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1203557283, COSV64185355; called by muse, mutect2, varscan2
- ALDH1A3 | c.585C>T p.L195= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as rs765289567, COSV60902914, COSV60903663; called by muse, mutect2, varscan2
- ALOX15B | c.1149C>G p.V383= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as COSV101205624; called by muse, mutect2
- ARV1 | c.747C>G p.V249= | Silent (SNP) | VAF 27/101 reads (27%) | catalogued as COSV59618568; called by muse, mutect2, varscan2
- ATP8B4 | c.672C>A p.L224= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs1250191722, COSV52722413; called by muse, mutect2, varscan2
- BCAT2 | c.285C>G p.L95= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as COSV60273761; called by muse, mutect2, varscan2
- BCKDK | c.786C>T p.F262= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as COSV54893496; called by muse, mutect2, varscan2
- BIRC6 | c.3681G>A p.V1227= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV70204287; called by muse, mutect2, varscan2
- CCL3L3 | c.159G>A p.E53= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs1409595267; called by muse, mutect2, varscan2
- CDHR5 | c.1284C>T p.F428= | Silent (SNP) | VAF 39/96 reads (41%) | catalogued as COSV57645563; called by muse, varscan2
- CETP | c.846C>T p.F282= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV52363582, COSV52363995; called by muse, mutect2
- CHD6 | c.4203G>A p.L1401= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV64693635; called by muse, varscan2
- CHPT1 | c.597G>A p.V199= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV57534559; called by muse, mutect2, varscan2
- CXXC1 | c.798C>T p.V266= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV53276423, COSV99497249; called by muse, mutect2, varscan2
- DOT1L | c.1599C>T p.L533= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV67108345; called by muse, mutect2, varscan2
- EFCAB5 | c.2469G>A p.L823= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as COSV57935465; called by muse, mutect2, varscan2
- ENDOU | c.657C>T p.F219= (on ENST00000422538 / NM_001172439.2; = p.F178= on NM_006025.4) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57465814; called by muse, mutect2, varscan2
- FRS2 | c.960C>T p.V320= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV54729050; called by muse, mutect2, varscan2
- FST | c.210G>A p.V70= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56816592; called by muse, mutect2, varscan2
- G2E3 | c.570A>G p.T190= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as COSV52842411; called by muse, mutect2, varscan2
- GLI3 | c.2223C>T p.L741= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs1280655354, COSV67893855; called by muse, mutect2, varscan2
- GLYATL2 | c.258G>A p.E86= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV54851119; called by muse, mutect2, varscan2
- GON4L | c.2392C>T p.L798= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1463278188; called by muse, mutect2, varscan2
- GPR4 | c.162C>T p.V54= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV59918000; called by muse, mutect2, varscan2
- GTSE1 | c.520C>T p.L174= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV71889649; called by muse, mutect2, varscan2
- H1-2 | c.540G>A p.A180= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as rs773564861, COSV59189483, COSV59190009, COSV59190715; called by muse, mutect2, varscan2
- HNF1A | c.729G>A p.Q243= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99982628; called by muse, mutect2
- INCA1 | c.93G>A p.Q31= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV61788655; called by muse, mutect2, varscan2
- INHA | c.858C>T p.F286= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV54728316; called by muse, mutect2, varscan2
- KIRREL1 | c.2229G>A p.S743= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs140671534; called by muse, varscan2
- KRT23 | c.675C>G p.V225= | Silent (SNP) | VAF 53/146 reads (36%) | catalogued as COSV52928799; called by muse, mutect2, varscan2
- LCAT | c.1065C>T p.F355= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as COSV50454501; called by muse, mutect2, varscan2
- LRRC8B | c.798C>T p.V266= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs1391084115, COSV58376693; called by muse, mutect2, varscan2
- LZTFL1 | c.744C>A p.L248= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV56112275; called by muse, mutect2, varscan2
- MAB21L2 | c.961C>T p.L321= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58262128; called by muse, mutect2, varscan2
- MACF1 | c.14709C>G p.L4903= (on ENST00000372915; = p.L2836= on NM_012090.5) | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV57138876; called by muse, mutect2, varscan2
- MACF1 | c.14808C>G p.V4936= (on ENST00000372915; = p.V2869= on NM_012090.5) | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV57138902; called by muse, mutect2, varscan2
- MCOLN1 | c.1119C>T p.I373= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs765687408, COSV51179385; called by muse, mutect2, varscan2
- MPND | c.567G>C p.L189= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99515203; called by muse, mutect2
- MROH1 | c.2484C>T p.I828= | Silent (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- MYO1D | c.2571C>A p.V857= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV59021561; called by muse, mutect2, varscan2
- NAT9 | c.279C>G p.L93= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV52854661; called by muse, mutect2, varscan2
- NCAPD2 | c.3369C>T p.D1123= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs1299524301, COSV59701834; called by muse, mutect2, varscan2
- NFE2L1 | c.2250C>T p.L750= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV62583701; called by muse, mutect2, varscan2
- NOP56 | c.36C>G p.V12= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs1272799475, COSV61391205; called by muse, varscan2
- NOTCH3 | c.4962G>T p.L1654= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs765985241, COSV54645737; called by muse, mutect2, varscan2
- OR4M1 | c.789A>G p.P263= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as COSV60063062; called by muse, mutect2, varscan2
- PDK1 | c.435C>T p.I145= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as rs758161432, COSV56376491, COSV56376795; called by muse, mutect2, varscan2
- PEX6 | c.2899C>T p.L967= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV55104978; called by muse, mutect2, varscan2
- PLA2G4F | c.144G>A p.V48= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV51828955; called by muse, mutect2, varscan2
- PNKP | c.1146C>G p.L382= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs751483948, COSV55589955; called by muse, mutect2
- PRAM1 | c.753G>A p.Q251= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV55316436; called by muse, mutect2, varscan2
- PRLR | c.582C>G p.L194= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV51499481; called by muse, mutect2, varscan2
- PRSS27 | c.741C>T p.I247= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1446191295, COSV100069605; called by muse, mutect2, varscan2
- PRSS8 | c.381C>G p.L127= | Silent (SNP) | VAF 46/165 reads (28%) | catalogued as COSV54898556; called by muse, mutect2, varscan2
- RFX1 | c.381G>A p.Q127= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV54332852; called by muse, mutect2, varscan2
- SEMA4G | c.162G>A p.Q54= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV52971276; called by muse, mutect2, varscan2
- SHC3 | c.555C>T p.I185= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV65440303; called by muse, varscan2
- SMPD4 | c.2001G>A p.Q667= (on ENST00000409031 / NM_017951.4; = p.Q638= on NM_017751.4) | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs1360510589, COSV100302529; called by muse, mutect2, varscan2
- SOHLH2 | c.1230G>A p.Q410= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs1407113202, COSV65903643; called by muse, mutect2, varscan2
- SPTBN5 | c.225C>T p.I75= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58026562; called by muse, mutect2, varscan2
- STK35 | c.1131C>G p.L377= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as COSV55692469; called by muse, mutect2, varscan2
- SYK | c.1044C>T p.Y348= | Silent (SNP) | VAF 82/183 reads (45%) | catalogued as rs142936514, COSV65325088; called by muse, mutect2, varscan2
- TAS2R20 | c.306C>T p.L102= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV67861652; called by muse, mutect2, varscan2
- TBC1D9 | c.3450G>A p.L1150= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV71308543; called by muse, mutect2, varscan2
- TLR2 | c.1770G>A p.L590= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV52607755; called by muse, mutect2, varscan2
- TRAK1 | c.1497G>T p.L499= (on ENST00000327628 / NM_001349247.2; = p.L441= on NM_014965.5) | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV58263065; called by muse, mutect2, varscan2
- TRIT1 | c.9C>T p.S3= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs946338022, COSV100381576; called by muse, mutect2
- TRPM2 | c.4452C>G p.L1484= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV55969987, COSV55978366; called by muse, mutect2, varscan2
- TTBK1 | c.327C>T p.L109= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99444710; called by muse, mutect2
- TXLNG | c.891G>A p.K297= | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as COSV66330390; called by muse, mutect2, varscan2
- ZBED1 | c.1798C>T p.L600= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV58137977; called by muse, mutect2, varscan2
- ZNF385D | c.408C>A p.T136= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs200837695, COSV55751511; called by muse, mutect2, varscan2
- ZNF638 | c.1314G>A p.L438= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV52494704; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81147499 C>T | 5'Flank (SNP) | VAF 5/47 reads (11%) | catalogued as rs369852873; called by muse, mutect2
- AP000769.3 | chr11:65505427 del TTAATAATAA | 5'Flank (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel, varscan2
- NACA | c.70+3981G>A | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100771378, COSV63272220; called by muse, mutect2
- OBSCN | c.11660-2454C>A | Intron (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99479405; called by muse, varscan2
- RUSC1 | c.-87+258C>T | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as COSV52741919; called by muse, mutect2, varscan2
- TBC1D3F | c.*47G>C | 3'UTR (SNP) | VAF 39/164 reads (24%) | catalogued as rs556181140; called by muse, mutect2, varscan2
